Surgical pathology report (de-identified scan), TCGA case TCGA-24-1428, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1428-01A (Primary Tumor).

[page 1 of 2]
TCGA-24-1458

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Physician(s):

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

DIAGNOSIS:

OVARY, LEFT, PORTION OF, EXCISION
- HIGH GRADE SEROUS CARCINOMA

OMENTUM, NODULE, EXCISION
- METASTATIC HIGH GRADE SEROUS CARCINOMA, 2.7 CM IN GREATEST DIMENSION

OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OMENTUM, OMENECTOMY
- METASTATIC HIGH GRADE SEROUS CARCINOMA

OVARY, LEFT, COMPLETION OOPHORECTOMY
- HIGH GRADE SEROUS CARCINOMA

Intraoperative Consultation:

"Brought to frozen 'part of right ovary,' consisting of a firm mass with a smooth surface measuring 9 x 5.5 x 3 cm and weighing 92 g. Sectioned to show a variegated tan to off-white cut surface. Section frozen as FS1. Rest for permanents," by [REDACTED]

"Called to pick up 'omental nodule,' consisting of a 7 x 6.5 x 4 cm portion of fatty tissue. Sectioned to show a 2.7 x 2.5 x 1.5 cm tan nodule tumor which is frozen as FS2. Rest for permanents," [REDACTED]

OR called to say that specimen #1 labeled right ovary is actually left ovary [REDACTED]

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location of the primary tumor is the left ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated

TUMOR INVASION

Tumor is not identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Metastatic involvement of the extrapelvic peritoneum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 8d73a066-83be-410e-a0d1-8a40275ca174 (TCGA-24-1428.9FCDD584-25E6-4A5A-AE15-F2956DE32822.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).